CGCI case BLGSP-71-22-00347 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7824ba74-2279-4833-9eb8-0db056a119e0

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 7 years; Vital status: Alive.

Diagnoses (1)
1. Burkitt-like lymphoma: ICD-O-3 morphology code: 9680/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Pelvis, NOS; Classification of tumor: primary; Age at diagnosis: 7.8 years (2,857 days); Year of diagnosis: 2014; Method of diagnosis: Excisional Biopsy; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 685 days (1.9 years); Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Sporadic, pediatric; Max tumor bulk site: Mesenteric lymph nodes; Sites of involvement: Liver / Small intestine / Kidney, NOS / Testes / Pleura.
   Pathology details: Lymph node involved site: Mesenteric.
   Pathology details: Lymph node involved site: Retroperitoneal.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Inguinal; Tumor largest dimension diameter: 10 cm.
   Pathology details: Lymph node involved site: Mediastinal.
   Pathology details: Lymph node involved site: Paraaortic.
   Pathology details: Lymph node involved site: Splenic.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: ANHL1131 (Group B + rituximab); Days to treatment start: 3 days; Days to treatment end: 118 days; Number of cycles: 4; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Etoposide + Prednisone + Rituximab + Vincristine; Initial disease status: Initial Diagnosis; Days to treatment start: 3 days; Days to treatment end: 118 days; Number of cycles: 4; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 0 days; Karnofsky performance status: 70.
- Days to follow up: 685 days (1.9 years); Disease response: Tumor Free.

Molecular and laboratory tests
- BCL2 (Flow Cytometry): Negative.
- BCL2 (IHC): Negative.
- BCL6 (Flow Cytometry): Positive; Specialized molecular test: BCL6 > 30%.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (Flow Cytometry): Positive; Specialized molecular test: CD10 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (Flow Cytometry): Positive.
- CD20 (IHC): Positive.
- CD3 (Flow Cytometry): Negative.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Abnormal, NOS.
- MYC translocation (FISH): Positive.
- Lactate Dehydrogenase 3334 [Blood test normal range upper: 840].
- Epstein-Barr Virus (ISH): Negative.

Other clinical attributes
- Day 0: Weight: 29 kg; Height: 124 cm; BMI: 18.9.

Biospecimens (3 samples)
- Sample BLGSP-71-22-00347-01A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Prospective.
- Sample BLGSP-71-22-00347-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample BLGSP-71-22-00347-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Lymphocytes; Preservation method: Frozen; Days to sample procurement: 3 days; Method of sample procurement: Blood Draw; Tissue collection type: Prospective.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), atypical morphology; Lymph nodes examined: No.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: para-aortic.
- Primary pathology, Extranodal involvement sites: Extranodal involvement site: Liver; Extranodal involvement site: Small Intestine; Extranodal involvement site: Kidney; Extranodal involvement site: Testicle; Extranodal involvement site: Pleura/Pleural Effusion.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Tests performed: LDH level: 3334; Immunophenotypic analysis method: Flow cytometry, not otherwise specified; Ebv status malignan cells method: EBER in situ hybridization.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunophenotypic analysis tested: CD3.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result: Genetic abnormality tested: C-myc.
- Follow-up form: Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Treatments, Treatment: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharma adjuvant cycles count: 4.
